Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A6G3, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A6G3-01A (Primary Tumor).

[page 1 of 5]
Gender **M**

Date Of Birth

Encounter Number

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

Results

Source of Specimen

- A. RIGHT PELVIC LYMPH NODES-NFS-
- B. RIGHT PELVIC LYMPH NODES-FS-
- C. LEFT PELVIC LYMPH NODES-NFS-
- D. LEFT PELVIC LYMPH NODES-FS-
- E. LEFT PERI-PROSTATIC TISSUE-FS-
- F. PROSTATE-

FINAL DIAGNOSIS:

- A. RIGHT PELVIC LYMPH NODES-NFS-
FIBROADIPOSE TISSUE AND FRAGMENTS OF LYMPH NODE TISSUE WITH NO
TUMOR SEEN.
- B. RIGHT PELVIC LYMPH NODES-FS-
THREE LYMPH NODES WITH NO TUMOR SEEN (0/3).
- C. LEFT PELVIC LYMPH NODES-NFS-
FIBROADIPOSE TISSUE AND FRAGMENTS OF LYMPH NODE TISSUE WITH NO
TUMOR SEEN.
- D. LEFT PELVIC LYMPH NODES-FS-
TWO LYMPH NODES WITH NO TUMOR SEEN (0/2).
- E. LEFT PERI-PROSTATIC TISSUE-FS-
FIBROADIPOSE TISSUE AND NEUROVASCULAR BUNDLE WITH FOCAL
ADENOCARCINOMA.

NOTE: TUMOR BEST SEEN ON ORIGINAL FROZEN SECTION SLIDE.

F. PROSTATE-

ADENOCARCINOMA OF PROSTATE (see synoptic report below).

SYNOPTIC REPORT:

ADENOCARCINOMA OF PROSTATE WITH INVASION OF BILATERAL SEMINAL

Prepared for

Discrepancy Primary Site		
Case to Clinical		

Final
ICD-O-3
Adenocarcinoma, acinar
8/40/13
Adenocarcinoma NDS
8/40/13
Site: Prostate NDS
C61.9
JW 7/5/13

[page 2 of 5]
VESICLES (THE LEFT GREATER THAN THE RIGHT)

EXTRAPROSTATIC SOFT TISSUE: INVOLVED

TUMOR SITE: BILATERAL

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 50 GRAMS

SIZE: 4.5 x 4 x 3.5 CM

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 4 + 4 = 8/10

SEVERITY IN EXTENT OF TUMOR: 5 /5

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

TNM STAGE: pT3b, pN0, pMX

LYMPHATIC (SMALL VESSEL) INVASION: IS SUSPECTED IN MULTIPLE FOCI

PERINEURAL INVASION: PRESENT

MARGIN STATUS:

- POSITIVE INKED MARGINS: BILATERAL SOFT TISSUES AROUND SEMINAL VESICLES
- NO TUMOR SEEN IN OTHER SPECIMEN MARGINS

Signature

(Case signed)

Signed Others

Frozen Section

A. RIGHT PELVIC LYMPH NODES, FS: 3 LYMPH NODES WITH NO TUMOR SEEN.

LEFT PELVIC LYMPH NODES, FS: 2 LYMPH NODES WITH NO TUMOR SEEN.

LEFT PERI-PROSTATIC TISSUE, FS: FIBROFATTY TISSUE WITH NERVE BUNDLES AND MINUTE FOCUS OF CARCINOMA CONSISTENT WITH PROSTATIC ORIGIN. NOTE: MULTIPLE LEVELS EXAMINED.

FS performed by

(Frozen Section Signed

Prepared for

[page 3 of 5]
Case Clinical Information
PROSTATE CANCER

Gross Description

- A. Received in formalin labeled with the patient's name and "right pelvic lymph nodes-NFS" are eight fragments of dissected fat measuring 2 x 2 x 2 cm in compact aggregate and showing minimal induration. All material is submitted in A1, A2.
- B. Received in formalin labeled with the patient's name and "right pelvic lymph nodes-FS" are three fragments of focally indurated fat measuring up to 2.2 x 1 x 0.2 cm thick. All material is submitted in B1.
- C. Received in formalin labeled with the patient's name and "left pelvic lymph nodes-NFS" are multiple fragments of fibroadipose tissue measuring 1.5 x 1.5 x 1.5 cm in compact aggregate. All material is submitted in C1.
- D. Received in formalin labeled with the patient's name and "left pelvic lymph nodes-FS" are four focally indurated pieces of fat measuring up to 1.8 x 1 x 0.2 cm. All material is submitted in D1.
- E. Received in formalin labeled with the patient's name and "left peri-prostatic tissue-FS" is an irregular, firm, brown/tan tissue measuring 9 x 7 x 2 mm thick. All material is submitted in E1.
- F. Received in formalin labeled with the patient's name and "prostate" is a 50 gram previously inked blue on the right and black on the left measuring 3.5 cm anterior to posterior x 4 cm superior to inferior x 4.5 cm right to left. The right and left seminal vesicles project from the right and left 2 x 1.5 x 1.2 cm and 1.5 x 1 x 0.8 cm with the stubs of the right and left vas measuring 1.5 x 0.3 cm on both sides. The superior aspect reveals a somewhat prominent median lobe bulging above the surface of the bladder aspect of the prostate. Both the distal urethral portion of prostate and proximal bladder portion shall be amputated from the remainder of the specimen sectioned parallel to the plane of the urethra and then totally submitted anterior to posterior. In addition, the area of the left seminal vesicle shall be more extensively sampled. On cross-sectioning, the prostate gland reveals a firm, focally nodular parenchyma. The section code is as follows:
F1-F3=distal urethral margin, totally submitted anterior to posterior; F4, F5=complete section of mid-prostate, anterior lobes; F6, F7=posterior lobes; F8, F9=complete section of upper third of prostate, anterior lobes; F10, F11=posterior lobes; F12-F14=remainder of posterior prostate; F15-F19=bladder aspect of prostate, totally submitted anterior to posterior; F20=shave projecting left seminal vesicle; F21=additional cross-sections

Prepared for

[page 4 of 5]
of left seminal vesicle; F22-F23=longitudinal sections of base of left seminal vesicle; F24=shave of right seminal vesicle and vas; F25=additional cross-sections of right projecting seminal vesicle and vas; and F26, F27=complete cross-section of junction of seminal vesicles, vasa and prostate. Note: sample removed for Research.

Physicians

Procedure

- A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- B. AA ROUTINE H&E X1 BLOCK
H&E X1
- C. AA ROUTINE H&E X1 BLOCK
H&E X1
- D. AA ROUTINE H&E X1 BLOCK
H&E X1
- E. AA ROUTINE H&E X1 BLOCK
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.3
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.4
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.5
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.6
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.7
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.8
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.9
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.10
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.11
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.12
H&E X1
- F. AA ROUTINE H&E X1 BLOCK.13

Prepared for

[page 5 of 5]
H&E X1
F. AA ROUTINE H&E X1 BLOCK.14
H&E X1
F. AA ROUTINE H&E X1 BLOCK.15
H&E X1
F. AA ROUTINE H&E X1 BLOCK.16
H&E X1
F. AA ROUTINE H&E X1 BLOCK.17
H&E X1
F. AA ROUTINE H&E X1 BLOCK.18
H&E X1
F. AA ROUTINE H&E X1 BLOCK.19
H&E X1
F. AA ROUTINE H&E X1 BLOCK.20
H&E X1
F. AA ROUTINE H&E X1 BLOCK.21
H&E X1
F. AA ROUTINE H&E X1 BLOCK.22
H&E X1
F. AA ROUTINE H&E X1 BLOCK.23
H&E X1
F. AA ROUTINE H&E X1 BLOCK.24
H&E X1
F. AA ROUTINE H&E X1 BLOCK.25
H&E X1
F. AA ROUTINE H&E X1 BLOCK.26
H&E X1
F. AA ROUTINE H&E X1 BLOCK.27
H&E X1

Prepared for

Source: NCI Genomic Data Commons file e6db8799-a82b-49ff-b6af-e86354cbd1c8 (TCGA-J4-A6G3.63F0D5A2-CCAB-48C7-9BD9-F75A699DE1AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).